CCDI case PBBSUK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/11e55c5c-8fc4-4611-b0fd-efcad7631702

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 6.3 years (2,303 days).

Biospecimens (3 samples)
- Sample 0DG388: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DG38A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DG38H: Tissue type: Tumor; Specimen type: Solid Tissue.
